Gene-level copy-number profile of tumor specimen TCGA-XE-AAOD-01A from TCGA case TCGA-XE-AAOD, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 39.1 years (14,265 days).
Specimen TCGA-XE-AAOD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.7264f8a4-344e-45f2-873e-e576c71765f6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XE-AAOD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/17d978aa-ea17-4b3d-9afe-86ea65f08a59

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 4,405; copy number 2: 39,295; copy number 3: 11,635; copy number 4: 3,170; copy number 5: 622; copy number 6: 15; copy number 8: 82; copy number 10: 366; copy number 12: 21; copy number 14: 23; copy number 16: 10; copy number 25: 169.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XE-AAOD-01A-11D-A434-01): tumor purity 0.17, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,308 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:64,024,409–98,479,225, 605 genes, copy number 5–10 (broad region; genes not listed).
- chr12:15,620,134–15,882,329, 1 gene, copy number 12 (within-gene range 4–12): EPS8.
- chr12:15,780,068–34,249,958, 319 genes, copy number 6–25 (broad region; genes not listed).
- chr14:18,333,726–23,326,185, 383 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,002. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
